Gene-level copy-number profile of tumor specimen TCGA-UW-A72K-01A from TCGA case TCGA-UW-A72K, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 52.8 years (19,303 days).
Specimen TCGA-UW-A72K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dbbbb0c1-a214-4173-a8a7-732d6ffa3179.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-UW-A72K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/5d47ca17-1d4f-4f27-9ebb-9caea64cbf14

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 523; copy number 1: 29,613; copy number 2: 28,779.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,354,987–120,355,148, 1 gene: U1.
- chr2:87,118,534–87,196,629, 3 genes: ANAPC1P3, AC083899.1, MIR4771-1.
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–1): RPS3AP15.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr6:31,307,815–31,308,549, 1 gene (within-gene range 0–1): AL671883.1.
- chr10:46,337,224–46,382,626, 3 genes (within-gene range 0–1): AGAP14P, FAM25BP, AC244230.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 27,269. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
